Gene-level copy-number profile of tumor specimen C3N-01716-03 from CPTAC case C3N-01716, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 50.2 years (18,343 days).
Specimen C3N-01716-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 462f1e7e-16ac-4402-9cd9-8a9aca70634f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01716-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: a second AscatNGS file.
https://portal.gdc.cancer.gov/files/9a20ac4a-b76d-49df-939b-3702a124ed2f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 2: 11,802; copy number 3: 3,355; copy number 4: 42,124; copy number 5: 446; copy number 6: 79; copy number 7: 327; copy number 8: 11; copy number 9: 91; copy number 10: 5; copy number 11: 17; copy number 13: 7; copy number 15: 21; copy number 16: 17; copy number 17: 61; copy number 30: 19; copy number 33: 3; copy number 54: 17.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 258 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:3,466,250–3,478,978, 1 gene, copy number 9: GAPLINC.
- chr18:20,946,906–21,241,371, 5 genes, copy number 10 (within-gene range 2–10): ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1.
- chr18:21,914,369–22,419,294, 14 genes, copy number 16: AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1.
- chr18:22,699,481–27,190,698, 82 genes, copy number 15–17 (broad region; genes not listed).
- chr18:28,638,714–29,548,241, 7 genes, copy number 13: AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1.
- chr19:9,466,355–11,079,426, 90 genes, copy number 9 (broad region; genes not listed).
- chr19:27,638,483–30,713,538, 59 genes, copy number 11–54 (within-gene range 2–54): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
